Somatic mutation profile of tumor specimen TCGA-CG-4436-01A (aliquot TCGA-CG-4436-01A-01D-1158-08) from TCGA case TCGA-CG-4436, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 57.3 years (20,941 days).
Specimen TCGA-CG-4436-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d654b9c0-71d2-420f-92c9-a36e88c2aa5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4436-10A (Blood Derived Normal), aliquot TCGA-CG-4436-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddd45d7e-92dd-4b58-beeb-168f4dbda5ad

The open-access MAF lists 167 somatic variants for this specimen: 125 protein-altering or splice-affecting, 38 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 38, Frame Shift Del 4, Nonsense Mutation 3, 5'Flank 2, Splice Site 1, 3'UTR 1, Splice Region 1, Intron 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2393T>C p.L798P | Missense Mutation (SNP) | VAF 12/156 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2
- KRT5 | c.1400T>C p.I467T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs60271599, CM970848, COSV52860383; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 54/102 reads (53%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1030A>G p.N344D | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.169); catalogued as COSV63974633; called by muse, mutect2
- AMPD3 | c.311C>T p.P104L (on ENST00000396553 / NM_001025389.2; = p.P113L on NM_000480.3) | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs770661067, COSV67330791; called by muse, mutect2, varscan2
- ANOS1 | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.915); catalogued as COSV52918391; called by muse, mutect2, varscan2
- ASCC3 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61228055; called by muse, mutect2
- ATF7IP | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV53770110; called by muse, mutect2
- B3GALT2 | c.128T>A p.F43Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV66464002; called by muse, mutect2, varscan2
- BRD2 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV66373116; called by muse, mutect2, varscan2
- CCDC138 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs370114556; called by muse, mutect2
- CCDC178 | c.2241A>T p.K747N (on ENST00000383096 / NM_001105528.3; = p.K709N on NM_198995.3) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as COSV55771501; called by muse, mutect2
- CCDC178 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760077046, COSV55767541; called by muse, mutect2, varscan2
- CCL8 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67013920; called by muse, mutect2, varscan2
- CCT8 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs530186629, COSV54502902; called by muse, mutect2
- CDH12 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101202082; called by muse, varscan2
- CFAP47 | c.5251A>T p.I1751F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV57973540; called by muse, mutect2, varscan2
- COL22A1 | c.3955C>T p.P1319S | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); catalogued as COSV57334611; called by muse, mutect2
- CPZ | c.163G>A p.A55T (on ENST00000360986 / NM_001014447.3; = p.A44T on NM_003652.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs145429481; called by muse, mutect2, varscan2
- CR1 | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65457889; called by muse, mutect2, varscan2
- CXCR2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199777583; called by muse, mutect2, varscan2
- CYLC1 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV61411679, COSV61416457; called by muse, mutect2, varscan2
- CYTH4 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1166726783, COSV50632135; called by muse, mutect2, varscan2
- DDI1 | c.1128A>C p.Q376H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV56371926, COSV56376530; called by muse, mutect2, varscan2
- DENND3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164686761, COSV52802220; called by muse, mutect2, varscan2
- DMD | c.5221T>G p.L1741V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63747107, COSV63789783; called by muse, mutect2, varscan2
- DMD | c.4090T>G p.L1364V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1252905257, COSV63751258; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH17 | c.11642C>T p.P3881L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780967834, COSV67753411; called by mutect2, varscan2
- DNAH3 | c.6467C>T p.P2156L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54518595; called by muse, mutect2, varscan2
- EEF1A1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58548541; called by muse, mutect2, varscan2
- EIF6 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV55769730; called by muse, mutect2
- ENOX1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748351168, COSV54897485; called by muse, mutect2, varscan2
- EPHA3 | c.620A>C p.K207T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV60693190, COSV60703581, COSV60705777; called by muse, mutect2, varscan2
- EPHA3 | c.1925T>G p.L642R | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60700624; called by muse, mutect2, varscan2
- EPHA5 | c.1929A>C p.K643N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.797); catalogued as COSV56642663; called by muse, mutect2
- FAM222B | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.654); catalogued as COSV57929386; called by muse, mutect2, varscan2
- FAT3 | c.4865T>A p.I1622N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53104310; called by muse, mutect2, varscan2
- FAT4 | c.3185T>G p.L1062R | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV67885321; called by muse, mutect2, varscan2
- FAT4 | c.8957T>G p.L2986R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.474); catalogued as COSV58682292; called by muse, mutect2
- FGA | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV57395470; called by muse, mutect2
- FNDC3B | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs780973777, COSV100395294, COSV61041286; called by muse, mutect2, varscan2
- FSTL5 | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100055479, COSV60187156, COSV60193080; called by muse, mutect2
- FZD10 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV57473364; called by muse, mutect2
- GABRA1 | c.1042A>G p.S348G | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.497); catalogued as COSV50099571, COSV99195668; called by muse, mutect2
- GPR176 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54444799; called by muse, mutect2, varscan2
- GYS2 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53922793; called by muse, mutect2
- HCN1 | c.637A>T p.I213F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57507382; called by muse, mutect2
- HSPA4L | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768194196, COSV56545185; called by muse, mutect2
- KCNQ5 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 132/427 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); catalogued as rs771263285, COSV59658299; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>C p.L966P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KCNV1 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV52085846; called by muse, mutect2, varscan2
- KMT2C | c.10192C>T p.R3398W | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746034306, COSV51434376; called by muse, mutect2
- KNTC1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61079884; called by muse, mutect2, varscan2
- LCE2C | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV64228398; called by muse, mutect2
- LIN9 | c.478-1G>A p.X160_splice (on ENST00000366808 / NM_001270410.2; = p.X105_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/87 reads (11%) | catalogued as COSV60244901; called by muse, mutect2, varscan2
- LRFN5 | c.1064T>G p.F355C | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53254193; called by muse, mutect2
- LRRIQ3 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV63043239; called by muse, mutect2, varscan2
- MAGEH1 | c.660A>C p.*220Yext*20 | Nonstop Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100746781, COSV61678793; called by muse, mutect2
- MITF | c.1190T>C p.L397P (on ENST00000448226 / NM_006722.3; = p.L297P on NM_000248.4) | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58831064; called by muse, mutect2, varscan2
- MSL2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV53863076; called by muse, mutect2, varscan2
- MYO3B | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201311373, COSV58698104; called by muse, mutect2, varscan2
- NAPEPLD | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58522067; called by muse, mutect2
- NCKAP5 | c.1615A>C p.S539R | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58440933; called by muse, mutect2, varscan2
- NME8 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.096); catalogued as COSV52249620; called by muse, mutect2
- NTRK2 | c.1925G>A p.G642D (on ENST00000323115 / NM_001369534.1; = p.G658D on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52862535; called by muse, mutect2
- NUP50 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61660990; called by muse, mutect2
- OPCML | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59420148; called by muse, mutect2, varscan2
- OR10A6 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59164986; called by muse, mutect2, varscan2
- OR1L3 | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59169679; called by muse, mutect2, varscan2
- OR4A15 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV59034939; called by muse, mutect2, varscan2
- OR5L2 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65723689, COSV65723879; called by muse, mutect2
- OSBPL2 | c.295G>A p.E99K (on ENST00000313733 / NM_144498.4; = p.E87K on NM_014835.4) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985192059, COSV58216399; called by muse, mutect2
- P2RY14 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV56377153, COSV56382120; called by muse, mutect2, varscan2
- PCDHGA8 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs754946327, COSV53937501; called by muse, mutect2, varscan2
- PCLO | c.4232A>C p.K1411T | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61631843; called by muse, mutect2
- PCSK5 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767412291, COSV65088213; called by muse, mutect2, varscan2
- PDE2A | c.2110A>T p.N704Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57805967; called by muse, mutect2
- PDHA2 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54778879; called by muse, mutect2, varscan2
- PEAK1 | c.4246G>C p.D1416H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1270007590, COSV56934362; called by muse, mutect2
- PLCZ1 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56851961; called by muse, mutect2, varscan2
- PRAMEF4 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.111); catalogued as COSV52438387; called by muse, mutect2, varscan2
- PTPRT | c.2661C>A p.Y887* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | catalogued as COSV61966418, COSV61977890; called by muse, mutect2
- PXDNL | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs375925669, COSV62486424; called by muse, mutect2, varscan2
- QSER1 | c.1144T>G p.S382A (on ENST00000399302; = p.S511A on NM_001076786.3) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV67900304; called by muse, mutect2, varscan2
- RHBDF1 | c.2470G>A p.V824I | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs369772748, COSV51954431, COSV51955702; called by muse, varscan2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- SCUBE3 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.919); catalogued as rs776672878, COSV51456459; called by muse, mutect2, varscan2
- SETD1A | c.3000G>C p.E1000D | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV52687291; called by muse, mutect2
- SHBG | c.764G>C p.G255A | Missense Mutation (SNP) | VAF 176/318 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV52646687; called by muse, mutect2, varscan2
- SHISAL1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs772497929, COSV66987863; called by muse, mutect2, varscan2
- SLC16A8 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1447856624, COSV57635187; called by muse, mutect2, varscan2
- SLC38A4 | c.717G>A p.V239= | Splice Region (SNP) | VAF 16/122 reads (13%) | catalogued as COSV56967075; called by muse, mutect2, varscan2
- SMU1 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs866865953, COSV68139808; called by muse, mutect2, varscan2
- SPICE1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs148983792; called by muse, mutect2, varscan2
- STXBP2 | c.858C>A p.D286E | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV55403009; called by muse, mutect2, varscan2
- SYCP2 | c.3280C>G p.R1094G | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1204850058, COSV62765923, COSV62768049, COSV62771039; called by muse, mutect2
- TBX18 | c.563C>G p.A188G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63736666; called by muse, mutect2
- TENM3 | c.6523T>C p.Y2175H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV69306328; called by muse, mutect2, varscan2
- THSD1 | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs1243849852, COSV51628120; called by muse, mutect2
- TJP1 | c.3780G>C p.K1260N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100632565; called by muse, mutect2
- TJP1 | c.3779A>C p.K1260T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100632567; called by muse, mutect2
- TM7SF3 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58002186; called by muse, mutect2, varscan2
- TMEM102 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53439589; called by muse, mutect2, varscan2
- TRIM22 | c.1074A>C p.E358D | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66090748; called by muse, mutect2, varscan2
- TRIML1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs777627581, COSV60194143; called by muse, mutect2, varscan2
- TTC27 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV58651077; called by muse, mutect2, varscan2
- TTN | c.67153G>A p.A22385T (on ENST00000591111; = p.A14961T on NM_003319.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | PolyPhen benign (0.21); catalogued as rs794729490, COSV60018652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2SURP | c.2261T>G p.F754C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.428); catalogued as COSV67530705; called by muse, mutect2, varscan2
- UQCC1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 16/331 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1236386711, COSV62902395; called by muse, mutect2
- USP11 | c.2137C>T p.R713C (on ENST00000218348; = p.R670C on NM_001371072.1) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1417404458, COSV54473491; called by muse, mutect2, varscan2
- USP8 | c.3259G>C p.E1087Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV56163996; called by muse, mutect2
- USPL1 | c.1934T>C p.I645T | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1314444331, COSV54999778; called by muse, varscan2
- VN1R1 | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV58090963; called by muse, mutect2
- WDR43 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56098675; called by muse, mutect2
- XIRP2 | c.4896C>G p.D1632E (on ENST00000628543; = p.D1807E on NM_152381.6) | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54696799; called by muse, mutect2, varscan2
- ZNF493 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs375638999; called by muse, mutect2, varscan2
- ZSCAN18 | c.314T>G p.V105G | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53732512; called by muse, mutect2
- ZSCAN4 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs780652384, COSV56591746; called by muse, mutect2, varscan2
- ZSWIM3 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54169253; called by muse, mutect2, varscan2
- CPNE8 | c.119_120del p.T40Ifs*3 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by pindel, varscan2
- MEX3B | c.354_356del p.E118del | In Frame Del (DEL) | VAF 10/29 reads (34%) | called by pindel, varscan2
- THBS4 | c.526del p.Q176Rfs*11 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- TTL | c.343_347del p.G115Sfs*6 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- USPL1 | c.1969del p.Q657Kfs*3 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | called by pindel, varscan2
- ZNF804A | c.2101A>G p.N701D | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- ACTL7B | c.195C>T p.Y65= | Silent (SNP) | VAF 121/307 reads (39%) | catalogued as COSV65927038; called by muse, mutect2, varscan2
- ACTN2 | c.1422C>T p.H474= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1282303942, COSV63974636; called by muse, mutect2
- ADAMTS4 | c.1023G>A p.P341= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs955762849, COSV63487750; called by muse, mutect2, varscan2
- ALPP | c.1251C>T p.N417= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs1234739541, COSV67396259; called by muse, mutect2, varscan2
- DKK4 | c.387A>C p.P129= | Silent (SNP) | VAF 29/588 reads (5%) | catalogued as COSV55182420; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2067C>T p.I689= | Silent (SNP) | VAF 78/187 reads (42%) | catalogued as rs750670890, COSV62567416; called by muse, mutect2, varscan2
- EPHA5 | c.2874A>G p.E958= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs771745177, COSV56642654; called by muse, mutect2, varscan2
- FAM110B | c.387G>A p.E129= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV64064876, COSV64068387; called by muse, mutect2, varscan2
- FEZ1 | c.234C>T p.N78= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as rs768255715, COSV54028218; called by muse, mutect2, varscan2
- FLG | c.2700A>G p.E900= | Silent (SNP) | VAF 44/848 reads (5%) | catalogued as COSV64241017; called by muse, mutect2
- GAL3ST1 | c.357C>T p.T119= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV58892445; called by muse, mutect2, varscan2
- IGLC7 | c.168C>T p.T56= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- IGSF10 | c.6114C>T p.A2038= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV56377159; called by muse, mutect2
- LTBP1 | c.4998C>T p.C1666= (on ENST00000404816 / NM_206943.4; = p.C1340= on NM_000627.4) | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs1165073566, COSV55378693; called by muse, mutect2, varscan2
- MIS18BP1 | c.291C>T p.P97= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs776797494, COSV60370604; called by muse, mutect2
- MUC21 | c.1662G>A p.S554= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs767681455, COSV66220718; called by muse, mutect2, varscan2
- MYO1H | c.147C>A p.R49= | Silent (SNP) | VAF 26/410 reads (6%) | catalogued as COSV60445310; called by muse, mutect2
- NBEA | c.6267T>G p.T2089= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59780179; called by muse, mutect2, varscan2
- NLRP14 | c.1131T>G p.T377= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV55063944, COSV55066493; called by muse, mutect2, varscan2
- OR10H2 | c.903C>T p.A301= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100008810, COSV59945883; called by muse, mutect2
- OR4C15 | c.346T>C p.L116= (on ENST00000314644; = p.L62= on NM_001001920.2) | Silent (SNP) | VAF 23/330 reads (7%) | catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2
- OR5W2 | c.94T>C p.L32= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1214322255, COSV60614714, COSV60614862; called by muse, mutect2, varscan2
- PCDH18 | c.513C>G p.L171= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV61268053; called by muse, mutect2, varscan2
- PCDHB10 | c.417C>G p.V139= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as COSV53378190; called by muse, mutect2, varscan2
- PCLO | c.4707T>G p.A1569= | Silent (SNP) | VAF 19/349 reads (5%) | catalogued as COSV61623943, COSV61631831; called by muse, mutect2
- PPP2R3C | c.1302G>A p.E434= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV54832476; called by muse, mutect2
- PRKD1 | c.2154T>C p.D718= | Silent (SNP) | VAF 28/191 reads (15%) | catalogued as COSV59567129; called by muse, mutect2, varscan2
- PTPRS | c.427T>C p.L143= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV53618283; called by muse, mutect2, varscan2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2, varscan2
- SEMA6D | c.126G>A p.P42= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs750700486, COSV60376354; called by muse, mutect2, varscan2
- SLITRK1 | c.1683G>A p.P561= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs1041327542, COSV65675088; called by muse, mutect2, varscan2
- SLX4 | c.4524G>A p.S1508= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as rs1423670990, COSV53563538; ClinVar: uncertain significance; called by muse, mutect2
- SYT3 | c.1185C>T p.H395= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs747005566, COSV58895936; called by muse, mutect2, varscan2
- TRIM58 | c.165C>T p.Y55= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV63570009; called by muse, mutect2, varscan2
- VKORC1 | c.276A>T p.L92= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV54923985; called by muse, mutect2, varscan2
- ZIM2 | c.1210A>C p.R404= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55631890; called by muse, mutect2, varscan2
- ZNF281 | c.1722T>G p.V574= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV54166879; called by muse, mutect2, varscan2
- ZNRF4 | c.1065G>A p.V355= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as rs1357897306, COSV55773961; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825322 G>C | 5'Flank (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*3826G>A | 3'UTR (SNP) | VAF 60/202 reads (30%) | catalogued as rs760082580, COSV53973664; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>C | Intron (SNP) | VAF 11/280 reads (4%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2
- TRAPPC9 | chr8:140458522 ins C | 5'Flank (INS) | VAF 6/16 reads (38%) | catalogued as rs1377948647; called by mutect2, varscan2
